TCGA case TCGA-CQ-5332 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: University Health Network, Toronto. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/657346f2-4280-4d80-983e-cab8004f184a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 87 years; Vital status: Dead; Days to death: 317 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 87.7 years (32,032 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic stage: Stage III; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 31; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 317.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 90; Tobacco smoking quit year: 1998.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CQ-5332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-CQ-5332-01A-01-BS1: Section location: Bottom; Percent tumor cells: 93; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-CQ-5332-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-CQ-5332-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CQ-5332-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Anatomic organ subdivision: Floor of mouth; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol history documented: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 317 days; disease-specific survival: event status not recorded, 317 days; progression-free interval: no event (censored), 317 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CQ-5332-01A-01D-1682-01): tumor purity 0.64, ploidy 3.61, whole-genome doublings 1.
